Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A2OL, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A2OL-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Skin, left superior neck, excision
- Seborrheic keratosis, excised

B: Thyroid, right lobe, lobectomy

Tumor histologic type: papillary thyroid carcinoma, follicular variant, encapsulated

Tumor size: 2.9 cm

Tumor growth pattern: follicular variant
per TSS, follicular

Tumor focality: unifocal variant 7997

Extent of invasion:

Capsular Invasion: negative

Lymphovascular: negative

Blood vascular: negative

Extra thyroidal extension: negative

Surgical margins: not involved (closest approach is to <1 mm in block B3)

Lymph nodes: none sampled

Other significant findings: parathyroid, normocellular (B5)

AJCC PATHOLOGIC TNM STAGE: pT2 pNx pMx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old female with a thyroid mass on the right. CIS: Clin: Noted . Outside . reportedly showed follicular neoplasm, not reviewed here.

Gross Description:

Received are two appropriately labeled containers.

1CD-0-3

Carcinoma, papillary, follicular variant 8340/3

Site: thyroid, NOS C73.9

fw
8/24/11

[page 2 of 2]
Container A is additionally labeled "left superior neck lesion." It holds a 0.7 x 0.5 x 0.2 cm ellipse of granular, gray/tan unoriented skin which is inked, sectioned and entirely submitted with the tips in block A1 and the remainder in block A2,

Container B is additionally labeled "right thyroid." It holds a 16.4 gram, 4.4 x 3.5 x 2.0 cm right lobe of thyroid which is inked as follows: anterior=blue, posterior=black, isthmus=yellow. The specimen is sectioned to reveal a 2.9 x 2.8 x 2.7 cm solid, fleshy, tan/pink circumscribed nodule. The surrounding thyroid tissue is dark red/brown and homogeneous with no additional lesions noted. The nodule focally abuts the blue inked anterior margin, as well as the black inked posterior margin but appears confined to the gland. The nodule is 1.2 cm from the isthmus margin of resection. The specimen is entirely submitted from superior towards inferior.

Block summary:

(Inking: anterior=blue, posterior=black, isthmus=yellow)

B1-B14 - superior towards inferior, respectively,

Light Microscopy:

Light microscopic examination is performed by Dr.

Sections show an encapsulated 2.9 cm diameter microfollicular neoplasm with papillary carcinoma cytology, including nucleomegaly, chromatin clearing, nuclear grooves, and pseudoinclusions. No psammoma bodies are noted. No capsular or vascular invasion is noted. Dr. concurs.

Source: NCI Genomic Data Commons file e1c619ab-06f2-4813-bc92-dfdfeab4b538 (TCGA-DE-A2OL.2562FA10-66F8-41BF-B73E-8D78EBEDD7EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).